Somatic mutation profile of tumor specimen C3N-02010-03 (aliquot CPT0241500007) from CPTAC case C3N-02010, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.3 years (22,742 days).
Specimen C3N-02010-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1cfdd0c-a289-4350-b10f-35e41db49d69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02010-31 (Blood Derived Normal), aliquot CPT0241760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2342ddc4-adc1-49b7-8820-ca78e8a65817

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, 5'Flank 2, Intron 2, Frame Shift Del 1, Nonsense Mutation 1, RNA 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 94/286 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 122/322 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- IGSF8 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs373796213; called by muse, mutect2, varscan2
- KIF26A | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 92/352 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs1462761829; called by muse, mutect2, varscan2
- KL | c.2047C>A p.L683I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as rs372004513; called by muse, mutect2, varscan2
- LEMD3 | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 44/397 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV57654022; called by muse, mutect2, varscan2
- MAP3K13 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 46/442 reads (10%) | catalogued as COSV53983886; called by muse, mutect2, varscan2
- MUC16 | c.16829G>A p.R5610Q | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.199); catalogued as rs761072024, COSV67470593; called by muse, mutect2, varscan2
- MYH6 | c.3787G>A p.V1263M | Missense Mutation (SNP) | VAF 175/614 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs375819633, COSV62452964; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- QRICH2 | c.4945C>T p.R1649W | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748067581; called by muse, mutect2, varscan2
- RYR2 | c.6320C>T p.T2107M | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs370331492, COSV63669380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC9A3 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 65/448 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1393947888, COSV53800318; called by muse, mutect2, varscan2
- VPS13A | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.423); catalogued as rs201208791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBB3 | c.65A>G p.D22G | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL11A1 | c.494A>T p.H165L | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAT1 | c.634T>G p.Y212D | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- GPBAR1 | c.178_187del p.A60Sfs*53 | Frame Shift Del (DEL) | VAF 80/310 reads (26%) | called by mutect2, pindel, varscan2
- IRX2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- KREMEN1 | c.1222G>T p.V408L (on ENST00000407188; = p.V410L on NM_032045.5) | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCAM2 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2G12B | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RMC1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SUPT20HL2 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAF3IP2 | c.1386+1G>A p.X462_splice | Splice Site (SNP) | VAF 26/142 reads (18%) | called by muse, mutect2, varscan2
- ZNF215 | c.1276C>G p.Q426E | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ZNF746 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB5 | c.441T>A p.V147= | Silent (SNP) | VAF 38/132 reads (29%) | called by muse, mutect2, varscan2
- KIF21A | c.4779G>A p.V1593= (on ENST00000361418 / NM_001378440.1; = p.V1580= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/139 reads (40%) | catalogued as COSV62775337; called by muse, mutect2, varscan2
- LRRC7 | c.1611G>T p.L537= (on ENST00000651989 / NM_001370785.2; = p.L504= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2
- NCR2 | c.168G>A p.K56= | Silent (SNP) | VAF 88/580 reads (15%) | catalogued as rs865913443; called by muse, mutect2, varscan2
- NOS3 | c.993C>T p.Y331= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as rs370490675; called by muse, mutect2, varscan2
- PDE3A | c.219G>C p.L73= | Silent (SNP) | VAF 52/160 reads (33%) | called by muse, mutect2
- SORCS1 | c.2514C>T p.G838= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs144932995; called by muse, mutect2, varscan2
- ZFP42 | c.114G>A p.A38= | Silent (SNP) | VAF 19/376 reads (5%) | catalogued as rs1241816484, COSV58818092; called by muse, mutect2
- AP000769.3 | chr11:65505172 del TTTA | 5'Flank (DEL) | VAF 32/136 reads (24%) | called by mutect2, pindel, varscan2
- DUOXA2 | c.554+10G>T | Intron (SNP) | VAF 74/226 reads (33%) | catalogued as rs1405201674; called by muse, mutect2, varscan2
- HMBS | c.161-69_161-53del | Intron (DEL) | VAF 82/362 reads (23%) | called by mutect2, pindel, varscan2
- MFRP | chr11:119346276 C>T | 5'Flank (SNP) | VAF 152/708 reads (21%) | called by muse, mutect2, varscan2
- RGS19 | c.-30C>T | 5'UTR (SNP) | VAF 9/25 reads (36%) | catalogued as COSV58657837; called by muse, mutect2, varscan2
- Vault | n.72C>T | RNA (SNP) | VAF 37/129 reads (29%) | catalogued as rs954556926; called by muse, mutect2, varscan2
